CGCI case BLGSP-71-23-00361 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5ca4df45-0803-4b2e-a15b-0ac053aba5bb

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 9 years; Vital status: Dead; Days to death: 328 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 9.4 years (3,427 days); Year of diagnosis: 2016; Method of diagnosis: Excisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 328 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Retroperitoneal lymph nodes; Sites of involvement: Adrenal gland, NOS / Peritoneum, NOS / Liver / Kidney, NOS.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Retroperitoneal; Tumor largest dimension diameter: 20 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide + Ifosfamide + Rituximab; Initial disease status: Progressive Disease; Days to treatment start: 178 days; Days to treatment end: 300 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Progressive Disease; Regimen or line of therapy: ICE; Days to treatment start: 178 days; Days to treatment end: 300 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS, for recurrent disease; adjuvant Radiation Therapy, NOS; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Karnofsky performance status: 60; ECOG performance status: 3.
- Days to follow up: 167 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 167 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 266 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS; Days to recurrence: 266 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 328 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 1177 [Blood test normal range upper: 618].

Other clinical attributes
- Day 0: Risk factors: Epstein-Barr Virus.
- Day 0: Comorbidities: Epstein-Barr Virus.
- Day 0: Weight: 28.9 kg; Height: 140 cm; BMI: 14.7.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-23-00361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00361-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
- Sample BLGSP-71-23-00361-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-23-00361-14A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS; Preservation method: FFPE; Tissue collection type: Retrospective.
  Slide BLGSP-71-23-00361-14A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 50.
  Slide BLGSP-71-23-00361-14A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 50.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- History of disease: History immunosuppresive diagnosis other: Epstein Barr and Cytomegalovirus.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Adrenal; Extranodal involvement site: Ascites/Peritoneum; Extranodal involvement site: Liver; Extranodal involvement site: Kidney.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 1177.
- New tumor event: New tumor event type: Locoregional Recurrence; New tumor event surgery: Yes; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, New tumor event: New tumor event type: Locoregional Recurrence; New tumor event site other: CNS and medular; New tumor event diagnosis evidence: Convincing Imaging; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment: Therapy regimen: Progression after initial; Chemo end reporting period: Yes; Pharmaceutical regimen: ICE + Rituxumab; Treatment best response: Clinical Progressive Disease.
